Somatic mutation profile of tumor specimen TCGA-BC-A10R-01A (aliquot TCGA-BC-A10R-01A-11D-A12Z-10) from TCGA case TCGA-BC-A10R, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; Tumor grade: G2; Age at diagnosis: 66.5 years (24,274 days).
Specimen TCGA-BC-A10R-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) daf6c6a3-306e-45eb-9fad-44aff7c984eb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BC-A10R-11A (Solid Tissue Normal), aliquot TCGA-BC-A10R-11A-11D-A12Z-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2f3c79a5-e198-4daa-a5f1-8f7cdc4fb846

The open-access MAF lists 123 somatic variants for this specimen: 97 protein-altering or splice-affecting, 24 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 86, Silent 24, Nonsense Mutation 5, Frame Shift Ins 4, Splice Region 1, Splice Site 1, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.406C>T p.Q136* | Nonsense Mutation (SNP) | VAF 19/33 reads (58%) | hotspot (GDC flag); catalogued as CM971503, COSV52676850, COSV52715987, COSV52740951; called by muse, mutect2, varscan2
- ABCD1 | c.1120G>C p.E374Q | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0.029); catalogued as COSV54383845, COSV54384673; called by muse, mutect2, varscan2
- ACACB | c.2681C>T p.P894L | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.077); catalogued as COSV58130517; called by muse, mutect2, varscan2
- ACTR3 | c.529G>T p.V177F | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as COSV54299011, COSV99603842; called by muse, mutect2, varscan2
- AKAP6 | c.2998A>T p.K1000* | Nonsense Mutation (SNP) | VAF 36/116 reads (31%) | catalogued as COSV55208000; called by muse, mutect2, varscan2
- ANGPTL8 | c.386G>T p.S129I | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.112); catalogued as COSV52948700; called by muse, mutect2, varscan2
- ANKRD30A | c.2959G>C p.G987R (on ENST00000611781; = p.G931R on NM_052997.2) | Missense Mutation (SNP) | VAF 58/579 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0.031); catalogued as COSV64606539, COSV64609460; called by muse, mutect2
- ATP8A1 | c.1004G>A p.G335D | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT tolerated (0.68); PolyPhen benign (0.001); catalogued as COSV52530940; called by muse, mutect2, varscan2
- C20orf27 | c.355G>A p.E119K (on ENST00000379772 / NM_001258429.2; = p.E144K on NM_001039140.3) | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.15); catalogued as rs1239002127, COSV53923374; called by muse, mutect2, varscan2
- C5orf22 | c.136G>C p.V46L | Missense Mutation (SNP) | VAF 60/309 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV57597873; called by muse, mutect2, varscan2
- CAMTA2 | c.1339G>A p.D447N | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as rs1031912124, COSV61833897; called by muse, mutect2, varscan2
- CCDC39 | c.2767A>G p.R923G | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV56010044; called by muse, mutect2, varscan2
- CDHR1 | c.149T>C p.V50A | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as rs779048474, COSV60560549; called by muse, mutect2, varscan2
- CENPJ | c.3460A>T p.S1154C | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.412); catalogued as COSV67883170; called by muse, mutect2, varscan2
- CNOT4 | c.227A>G p.Q76R | Missense Mutation (SNP) | VAF 31/191 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as COSV59650744; called by muse, mutect2, varscan2
- COL6A6 | c.5582C>A p.A1861E | Missense Mutation (SNP) | VAF 19/119 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.09); catalogued as COSV62020410, COSV62025374; called by muse, mutect2, varscan2
- CRMP1 | c.1190G>A p.R397K | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.063); catalogued as COSV61478837; called by muse, mutect2, varscan2
- CRTC2 | c.996A>G p.P332= | Splice Region (SNP) | VAF 18/56 reads (32%) | catalogued as COSV57841524; called by muse, varscan2
- CSPG4 | c.6538G>A p.E2180K | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.7); PolyPhen benign (0.015); catalogued as rs370893364; called by muse, mutect2, varscan2
- CYP7A1 | c.778C>T p.R260C | Missense Mutation (SNP) | VAF 36/159 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56962835; called by muse, mutect2, varscan2
- EIF4G1 | c.1117G>T p.E373* (on ENST00000346169 / NM_198241.3; = p.E177* on NM_004953.5) | Nonsense Mutation (SNP) | VAF 19/121 reads (16%) | catalogued as COSV59989142, COSV59989818; called by muse, mutect2, varscan2
- FAHD2A | c.294C>A p.F98L | Missense Mutation (SNP) | VAF 48/354 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51977797; called by muse, mutect2, varscan2
- FBXO40 | c.1156A>T p.T386S | Missense Mutation (SNP) | VAF 8/95 reads (8%) | SIFT tolerated (0.9); PolyPhen benign (0.001); catalogued as COSV57522626; called by muse, mutect2
- FLNA | c.851C>T p.A284V | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.028); catalogued as COSV61039724, COSV61048145; called by muse, mutect2, varscan2
- FOXH1 | c.212G>T p.R71M | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.167); catalogued as COSV56760392; called by muse, mutect2, varscan2
- FZD10 | c.1502T>C p.V501A | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.449); catalogued as COSV57472591; called by muse, varscan2
- GABRA5 | c.52T>G p.F18V | Missense Mutation (SNP) | VAF 46/215 reads (21%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV59477091, COSV59478042; called by muse, mutect2, varscan2
- GALNT5 | c.2749A>T p.I917F | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV52036523; called by muse, mutect2, varscan2
- GJA8 | c.781C>T p.Q261* | Nonsense Mutation (SNP) | VAF 30/62 reads (48%) | catalogued as COSV53788173; called by muse, mutect2, varscan2
- GLO1 | c.47C>T p.A16V | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.36); PolyPhen benign (0.013); catalogued as COSV64905075; called by muse, mutect2, varscan2
- GON4L | c.5819G>A p.R1940K | Missense Mutation (SNP) | VAF 25/201 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.058); catalogued as COSV55189554; called by muse, mutect2, varscan2
- GSTK1 | c.466C>A p.L156M | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV64424083; called by muse, mutect2, varscan2
- HOXA4 | c.916C>T p.P306S | Missense Mutation (SNP) | VAF 52/303 reads (17%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.031); catalogued as COSV57828265; called by muse, mutect2, varscan2
- HOXA4 | c.915T>A p.H305Q | Missense Mutation (SNP) | VAF 53/301 reads (18%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.041); catalogued as COSV100415687; called by muse, mutect2, varscan2
- HPD | c.722A>G p.N241S | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as rs1276998235, CM078369, COSV56641355; called by muse, mutect2, varscan2
- IFNW1 | c.284G>T p.R95L | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.084); catalogued as COSV66521875; called by muse, mutect2, varscan2
- INF2 | c.1990A>G p.T664A | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.192); catalogued as COSV53030942; called by muse, mutect2, varscan2
- INO80 | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 56/293 reads (19%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.971); catalogued as COSV62736819; called by muse, mutect2, varscan2
- KCNA5 | c.1578A>T p.E526D | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.432); catalogued as COSV52904481; called by muse, mutect2, varscan2
- KIF26A | c.3425A>G p.D1142G | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV100181551; called by muse, mutect2, varscan2
- KLF8 | c.98G>A p.R33Q | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs144407506, COSV63847460; called by muse, mutect2, varscan2
- KNDC1 | c.4019G>T p.G1340V | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV58833410; called by muse, mutect2, varscan2
- LILRB4 | c.202C>G p.P68A | Missense Mutation (SNP) | VAF 60/304 reads (20%) | SIFT tolerated (0.97); PolyPhen benign (0.006); catalogued as COSV54404101; called by muse, mutect2, varscan2
- LMTK3 | c.209A>C p.K70T | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); catalogued as COSV54310611; called by muse, mutect2, varscan2
- MCM10 | c.20A>G p.N7S | Missense Mutation (SNP) | VAF 118/228 reads (52%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); catalogued as rs571506868, COSV66333459; called by muse, mutect2, varscan2
- MED24 | c.773G>A p.G258D | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.972); catalogued as rs762866058, COSV62417672; called by muse, mutect2, varscan2
- MISP | c.53G>C p.G18A | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV53119272; called by muse, mutect2, varscan2
- MROH2B | c.959A>C p.E320A | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.955); catalogued as COSV68182221; called by muse, mutect2
- MRPS22 | c.37C>T p.L13F | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.001); catalogued as rs748148830, COSV60349403; called by muse, mutect2, varscan2
- MTMR4 | c.1292C>T p.T431M | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60199716; called by muse, mutect2, varscan2
- MYBPC2 | c.1921C>A p.P641T | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV63094017; called by muse, mutect2, varscan2
- MYH6 | c.5696G>T p.R1899L | Missense Mutation (SNP) | VAF 24/118 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59305147; called by muse, mutect2, varscan2
- MYO18A | c.1052A>C p.K351T | Missense Mutation (SNP) | VAF 70/116 reads (60%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV62864113; called by muse, mutect2, varscan2
- NOL6 | c.1066G>C p.V356L | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV53040089; called by muse, mutect2, varscan2
- OR2T4 | c.724C>A p.P242T | Missense Mutation (SNP) | VAF 68/1022 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV63543585; called by muse, mutect2
- OR5R1 | c.335G>C p.C112S | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as COSV56571763; called by muse, mutect2
- OTOGL | c.4957G>A p.G1653R (on ENST00000547103; = p.G1644R on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/99 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.397); catalogued as COSV54014730; called by muse, mutect2, varscan2
- PATJ | c.2765A>C p.Q922P | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV57157767; called by muse, mutect2, varscan2
- PCDHGA5 | c.2347G>A p.E783K | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.049); catalogued as rs781103707, COSV53915854; called by muse, mutect2, varscan2
- PCSK4 | c.1094G>A p.C365Y | Missense Mutation (SNP) | VAF 63/117 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56298610; called by muse, mutect2, varscan2
- PDE6B | c.1333A>G p.K445E | Missense Mutation (SNP) | VAF 30/176 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as rs1424672145, COSV55324868; called by muse, mutect2, varscan2
- PDE8A | c.2017C>T p.H673Y | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59635548; called by muse, mutect2, varscan2
- PHKA2 | c.100T>G p.S34A | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.026); catalogued as COSV66052915; called by muse, mutect2, varscan2
- PLA2R1 | c.3401C>A p.T1134N | Missense Mutation (SNP) | VAF 128/406 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.857); catalogued as COSV51776340; called by muse, mutect2, varscan2
- PRICKLE2 | c.499G>A p.E167K (on ENST00000295902; = p.E111K on NM_198859.4) | Missense Mutation (SNP) | VAF 33/131 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs763649839, COSV55764208; called by muse, mutect2, varscan2
- PSG11 | c.209G>A p.G70E | Missense Mutation (SNP) | VAF 19/170 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV60454177; called by muse, mutect2, varscan2
- PSG9 | c.965A>C p.N322T | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.369); catalogued as COSV52484000; called by muse, mutect2, varscan2
- PTPN22 | c.1327C>A p.P443T (on ENST00000359785 / NM_001193431.2; = p.P388T on NM_012411.5) | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.691); catalogued as COSV63084519; called by muse, mutect2, varscan2
- RAPGEF3 | c.1922T>C p.L641P (on ENST00000389212; = p.L599P on NM_006105.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/132 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as COSV50199373; called by muse, mutect2, varscan2
- RETREG1 | c.1460C>T p.S487L (on ENST00000306320 / NM_001034850.2; = p.S346L on NM_019000.4) | Missense Mutation (SNP) | VAF 52/111 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.335); catalogued as COSV60447309; called by muse, mutect2, varscan2
- RTF2 | c.164+2T>A p.X55_splice | Splice Site (SNP) | VAF 10/41 reads (24%) | catalogued as COSV50128060; called by muse, mutect2, varscan2
- RYR2 | c.13145T>A p.L4382Q | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV63671439; called by muse, mutect2, varscan2
- SCML2 | c.835C>G p.Q279E | Missense Mutation (SNP) | VAF 60/277 reads (22%) | SIFT tolerated (0.47); PolyPhen benign (0.029); catalogued as COSV52619291; called by muse, mutect2, varscan2
- SIRPG | c.243A>C p.K81N | Missense Mutation (SNP) | VAF 270/749 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.265); catalogued as COSV53806498; called by muse, mutect2, varscan2
- SLC17A9 | c.74C>T p.A25V | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1397666755, COSV64846965; called by muse, mutect2, varscan2
- SMPD4 | c.575C>A p.P192Q | Missense Mutation (SNP) | VAF 29/145 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as COSV60079083, COSV60081308; called by muse, mutect2, varscan2
- SOCS6 | c.820G>C p.V274L | Missense Mutation (SNP) | VAF 51/150 reads (34%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); catalogued as COSV67546106; called by muse, mutect2, varscan2
- SPTBN4 | c.6752G>A p.R2251Q | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.005); catalogued as rs1455693385, COSV58945530; called by muse, mutect2, varscan2
- STAG3 | c.2675C>A p.S892* | Nonsense Mutation (SNP) | VAF 6/42 reads (14%) | catalogued as COSV57928475; called by muse, mutect2, varscan2
- STING1 | c.1127C>A p.T376K | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.321); catalogued as rs370381358, COSV58172189; called by muse, mutect2, varscan2
- SYNJ1 | c.3062G>A p.S1021N | Missense Mutation (SNP) | VAF 69/218 reads (32%) | SIFT tolerated (0.52); PolyPhen benign (0.015); catalogued as COSV59145865; called by muse, mutect2, varscan2
- TCF20 | c.4564T>A p.S1522T | Missense Mutation (SNP) | VAF 22/322 reads (7%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.003); catalogued as COSV59489284; called by muse, mutect2
- TDRD9 | c.2477C>T p.T826I | Missense Mutation (SNP) | VAF 36/113 reads (32%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as COSV59143963; called by muse, mutect2, varscan2
- TECR | c.856C>A p.H286N | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53107873; called by muse, mutect2, varscan2
- TFPT | c.503C>T p.P168L | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as rs774342975, COSV57837289; called by muse, mutect2, varscan2
- TRAF3IP1 | c.626G>T p.G209V | Missense Mutation (SNP) | VAF 30/185 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.175); catalogued as COSV64852267; called by muse, mutect2, varscan2
- TTC5 | c.785A>G p.Q262R | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV51870481; called by muse, mutect2, varscan2
- UNC79 | c.2821G>A p.E941K (on ENST00000393151 / NM_001346218.2; = p.E764K on NM_020818.5) | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.006); catalogued as rs780979845, COSV56379184; called by muse, mutect2, varscan2
- WDR62 | c.2087G>A p.S696N | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.268); catalogued as COSV99544206; called by muse, mutect2, varscan2
- XDH | c.251C>T p.A84V | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101052464; called by muse, mutect2, varscan2
- ZNF263 | c.573A>T p.L191F | Missense Mutation (SNP) | VAF 29/163 reads (18%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs763297120, COSV54595732; called by muse, mutect2, varscan2
- ZNF440 | c.173A>G p.N58S | Missense Mutation (SNP) | VAF 100/384 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.573); catalogued as COSV100407733; called by muse, varscan2
- ARFGAP2 | c.485dup p.A163Cfs*8 | Frame Shift Ins (INS) | VAF 10/24 reads (42%) | called by mutect2, pindel
- ATP9B | c.2844_2845dup p.F949Cfs*34 | Frame Shift Ins (INS) | VAF 50/214 reads (23%) | called by mutect2, pindel, varscan2
- BAP1 | c.1986dup p.D663* | Frame Shift Ins (INS) | VAF 57/100 reads (57%) | called by mutect2, pindel, varscan2
- COMMD3-BMI1 | c.193dup p.A65Gfs*15 | Frame Shift Ins (INS) | VAF 43/307 reads (14%) | called by mutect2, pindel, varscan2
- PCLO | c.3410T>A p.M1137K | Missense Mutation (SNP) | VAF 12/339 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- DMD | c.8766C>T p.S2922= | Silent (SNP) | VAF 44/260 reads (17%) | catalogued as rs149776669, COSV58897982; ClinVar: likely benign; called by muse, mutect2, varscan2
- DUSP10 | c.720C>T p.T240= | Silent (SNP) | VAF 19/149 reads (13%) | catalogued as COSV60456919; called by muse, mutect2, varscan2
- ENPP7 | c.1353G>A p.V451= | Silent (SNP) | VAF 14/33 reads (42%) | catalogued as COSV60385877; called by muse, mutect2, varscan2
- FBXO9 | c.753C>T p.Y251= | Silent (SNP) | VAF 44/225 reads (20%) | catalogued as rs776871324, COSV55055206; called by muse, varscan2
- FLNC | c.5061G>A p.G1687= | Silent (SNP) | VAF 10/66 reads (15%) | catalogued as COSV57952555; called by muse, mutect2, varscan2
- IMPG2 | c.1161A>T p.G387= | Silent (SNP) | VAF 17/55 reads (31%) | catalogued as COSV51975138; called by muse, mutect2, varscan2
- KIF26B | c.3207C>A p.G1069= | Silent (SNP) | VAF 6/62 reads (10%) | called by muse, mutect2
- MYOCD | c.2343C>T p.P781= | Silent (SNP) | VAF 33/54 reads (61%) | catalogued as COSV58499768; called by muse, mutect2, varscan2
- OR2G6 | c.12C>T p.T4= | Silent (SNP) | VAF 70/203 reads (34%) | catalogued as COSV100598116, COSV58573972; called by muse, mutect2, varscan2
- OR2T10 | c.276C>A p.I92= | Silent (SNP) | VAF 28/168 reads (17%) | catalogued as COSV57896350, COSV57898253; called by muse, mutect2, varscan2
- OR2T6 | c.717C>T p.A239= | Silent (SNP) | VAF 77/279 reads (28%) | catalogued as rs148186126, COSV100861487, COSV63215937; called by muse, mutect2, varscan2
- OR52E8 | c.207G>T p.L69= | Silent (SNP) | VAF 20/102 reads (20%) | catalogued as COSV66205396, COSV66208226; called by muse, mutect2, varscan2
- PCDH19 | c.2187A>T p.I729= | Silent (SNP) | VAF 36/145 reads (25%) | catalogued as COSV55259508; called by muse, mutect2, varscan2
- PLS1 | c.132C>T p.S44= | Silent (SNP) | VAF 8/69 reads (12%) | catalogued as rs753381485, COSV61833131; called by mutect2, varscan2
- PRICKLE3 | c.1800C>T p.R600= | Silent (SNP) | VAF 18/86 reads (21%) | catalogued as COSV66234138; called by muse, mutect2, varscan2
- PRR12 | c.3240G>A p.S1080= (on ENST00000615927; = p.S1901= on NM_020719.3) | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as rs780582166, COSV69816907; called by muse, mutect2, varscan2
- SEMA3D | c.1077G>C p.V359= | Silent (SNP) | VAF 14/62 reads (23%) | catalogued as COSV52389707; called by muse, mutect2, varscan2
- SEMA3F | c.873G>T p.A291= | Silent (SNP) | VAF 10/23 reads (43%) | catalogued as COSV50028701; called by muse, mutect2, varscan2
- SFMBT2 | c.1012C>T p.L338= | Silent (SNP) | VAF 10/93 reads (11%) | catalogued as COSV100738613, COSV62806810; called by muse, mutect2, varscan2
- SLC9A5 | c.66G>A p.Q22= | Silent (SNP) | VAF 7/10 reads (70%) | catalogued as COSV50759332; called by muse, mutect2
- SSX7 | c.432A>G p.K144= | Silent (SNP) | VAF 164/962 reads (17%) | catalogued as COSV53339575; called by muse, mutect2, varscan2
- TRPM1 | c.3774T>G p.L1258= | Silent (SNP) | VAF 16/77 reads (21%) | catalogued as COSV56632004; called by muse, mutect2, varscan2
- WBP11 | c.513A>G p.S171= | Silent (SNP) | VAF 34/146 reads (23%) | catalogued as COSV53762177; called by muse, mutect2, varscan2
- ZSCAN25 | c.1209C>T p.Y403= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as rs746704278, COSV53552343; called by muse, mutect2, varscan2
- IGKV2OR22-4 | n.83T>A | RNA (SNP) | VAF 9/91 reads (10%) | called by muse, mutect2, varscan2
- MICAL3 | c.2242-3454C>T | Intron (SNP) | VAF 11/56 reads (20%) | catalogued as rs201286172, COSV52894158; called by muse, mutect2, varscan2
